Gene-level copy-number profile of tumor specimen TCGA-WE-A8ZQ-06A from TCGA case TCGA-WE-A8ZQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 52.8 years (19,303 days).
Specimen TCGA-WE-A8ZQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c7bc32b2-e4a4-4b02-aa36-21a186c78c3a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-WE-A8ZQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a7093d1-7ac3-483e-aff6-4836ce01cf86

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,006; copy number 2: 10,744; copy number 3: 25,591; copy number 4: 11,641; copy number 5: 5,297; copy number 6: 750; copy number 7: 2,771; copy number 9: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-WE-A8ZQ-06A-41D-A371-01): tumor purity 0.94, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,214,672, 9 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr16:89,613,308–89,657,738, 2 genes: DPEP1, CHMP1A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,778 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:61,574,328–62,611,327, 7 genes, copy number 9: MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr7:70,972–148,420,998, 2,771 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,006. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
